Somatic mutation profile of tumor specimen TCGA-AB-2807-03D (aliquot TCGA-AB-2807-03D-01W-0755-09) from TCGA case TCGA-AB-2807, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.8 years (25,143 days).
Specimen TCGA-AB-2807-03D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1255b74-785b-46c3-907c-b177673368c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2807-11B (Solid Tissue Normal), aliquot TCGA-AB-2807-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c32dc57c-8bf2-495f-aaca-c2778e10a934

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, 5'Flank 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA2 | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55105921; called by muse, varscan2
- AKAP12 | c.4216G>A p.V1406I | Missense Mutation (SNP) | VAF 144/306 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53583604; called by muse, mutect2, varscan2
- GCN1 | c.7270C>T p.R2424W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56102972; called by muse, mutect2, varscan2
- KRT20 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764730297, COSV51426070; called by muse, mutect2, varscan2
- PCLO | c.13313G>A p.R4438H | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs773610201, COSV61618185; called by muse, mutect2, varscan2
- SAXO2 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.087); catalogued as rs933256705, COSV59755623; called by muse, mutect2, varscan2
- TBC1D8 | c.2456A>C p.E819A | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV65217364; called by muse, mutect2, varscan2
- TENM3 | c.3467G>A p.R1156H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1393753481, COSV69320762; called by muse, mutect2, varscan2
- TYRO3 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV55481030; called by muse, mutect2, varscan2
- USP6 | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.268); catalogued as COSV51499300; called by muse, mutect2, varscan2
- ASXL1 | c.2213del p.G738Dfs*6 | Frame Shift Del (DEL) | VAF 23/49 reads (47%) | called by mutect2, pindel, varscan2
- RUNX1 | c.420_425del p.S140_G141del (on ENST00000344691 / NM_001001890.3; = p.S167_G168del on NM_001754.5) | In Frame Del (DEL) | VAF 31/74 reads (42%) | called by mutect2, pindel, varscan2
- CTTNBP2NL | c.363G>A p.R121= | Silent (SNP) | VAF 122/276 reads (44%) | catalogued as COSV54747572; called by mutect2, varscan2
- KRT5 | c.1314C>A p.A438= | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as COSV52863948, COSV99357963; called by muse, varscan2
- TSPOAP1 | chr17:58331264 T>C | 5'Flank (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
